CCDI case PBCJEF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/7ce4e1f0-a191-47bf-837e-3c71d9b6151c

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pleuropulmonary blastoma: ICD-O-3 morphology code: 8973/3; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 0.9 years (345 days).

Biospecimens (3 samples)
- Samples 0DU4UN, 0DU4VJ (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU4V2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
